Somatic mutation profile of tumor specimen TCGA-X4-A8KS-01A (aliquot TCGA-X4-A8KS-01A-12D-A364-08) from TCGA case TCGA-X4-A8KS, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.8 years (22,571 days).
Specimen TCGA-X4-A8KS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee5a48f7-3ba9-4a87-8daa-9f9355640c39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X4-A8KS-10A (Blood Derived Normal), aliquot TCGA-X4-A8KS-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02ffb7c5-f410-4855-84d0-0fa78edb51bb

The open-access MAF lists 22 somatic variants for this specimen: 21 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 18, Frame Shift Del 1, Silent 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.392G>T p.W131L | Missense Mutation (SNP) | VAF 6/102 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV61653907, COSV61656320; called by muse, mutect2
- AL592490.1 | c.1363A>G p.T455A | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV101308128; called by muse, mutect2, varscan2
- CCDC186 | c.2320C>T p.R774W | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1180864229; called by muse, mutect2
- COL19A1 | c.524G>C p.G175A | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.817); catalogued as COSV100505609; called by muse, mutect2, varscan2
- EGR1 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.86); catalogued as COSV53518056; called by muse, mutect2
- EHBP1 | c.1736T>C p.V579A | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV99860322; called by muse, mutect2
- FAM171B | c.1231C>A p.H411N | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.945); catalogued as COSV100488786, COSV59005945; called by muse, mutect2, varscan2
- GRM7 | c.2714dup p.K906Efs*6 | Frame Shift Ins (INS) | VAF 5/48 reads (10%) | catalogued as rs777442128; called by pindel, varscan2
- HNRNPH2 | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1555988422, COSV54510124, COSV54510717, COSV99516238; ClinVar: uncertain significance; called by muse, mutect2
- LCE4A | c.195C>A p.H65Q | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV100139991; called by muse, mutect2
- MFSD6L | c.425C>G p.A142G | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.819); catalogued as COSV100266257; called by muse, mutect2
- NWD1 | c.1337G>C p.R446P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.425); catalogued as COSV100341939; called by muse, varscan2
- PCDHB7 | c.1665C>A p.N555K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV50753531, COSV99176308; called by muse, mutect2, varscan2
- PCNA | c.319+1G>A p.X107_splice | Splice Site (SNP) | VAF 19/263 reads (7%) | catalogued as rs112672560, COSV100996229; called by muse, mutect2
- RAP1A | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV100712706; called by muse, mutect2
- SEMA3C | c.1192G>C p.V398L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.405); catalogued as COSV99542543; called by muse, mutect2
- SLC4A7 | c.1661A>G p.N554S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as rs370056312; called by muse, varscan2
- SLC9C2 | c.913A>T p.I305F | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV100876622, COSV62945663; called by muse, mutect2, varscan2
- STAB2 | c.2216A>G p.Q739R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1180178917, COSV101185724; called by muse, mutect2, varscan2
- ZBTB7C | c.548T>G p.I183S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100134306, COSV100134491; called by muse, mutect2
- HDAC1 | c.863del p.V288Afs*9 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- MSH2 | c.477A>G p.R159= | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as COSV99253429; called by muse, mutect2
